Surgical pathology report (de-identified scan), TCGA case TCGA-BB-8601, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-BB-8601-01A (Primary Tumor).

[page 1 of 2]
1. ANTERIOR FLOOR OF MOUTH (EXCISION): NEGATIVE FOR TUMOR.
.
2. POSTERIOR FLOOR OF MOUTH (EXCISION): NEGATIVE FOR TUMOR.
.
3. VENTRAL TONGUE MARGIN (EXCISION): NEGATIVE FOR TUMOR.
.
4. RETROMOLAR TRIGONE (EXCISION): NEGATIVE FOR TUMOR.
.
5. INNER TABLE MANDIBLE (EXCISION): BONE WITH FIBROSIS AND REACTIVE
CHANGES. NEGATIVE FOR TUMOR.
.
6. TEETH (EXTRACTION): GROSS ONLY DIAGNOSIS.
.
7. RIGHT NECK LEVEL 2 AND 3 (DISSECTION): MINUTE (<1MM) FOCUS OF
METASTATIC CARCINOMA IN ONE (1) OF THIRTEEN (13) LYMPH NODES.
.
8. LEVEL ONE LYMPH NODE (EXCISION): THREE (3) LYMPH NODES AND
ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
.
9. FLOOR OF MOUTH ALVEOLI TUMOR (EXCISION):
SPECIMEN TYPE:
Resection (specify type): Floor of mouth and marginal
mandibulectomy.
TUMOR SITE:
Oral Cavity.
TUMOR SIZE:
Greatest dimension at least 6.0cm.
HISTOLOGIC TYPE:
Carcinomas of upper aerodigestive tract: Squamous cell carcinoma,
conventional.
.
HISTOLOGIC GRADE:
G2: Moderately differentiated.
EXTENT OF INVASION
The carcinoma involves bone.
PRIMARY TUMOR (pT):
pT3: Tumor more than 4cm in greatest dimension.
.
REGIONAL LYMPH NODES (pN):
pN1: Single lymph node metastasis.
.
DISTANT METASTASIS (pM):
pMX
.
.
.
MARGINS:
Margins uninvolved by tumor (while the specimen margin is involved
seperately submitted margins are negative).
.
VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION:
Absent.
.
PERINEURAL INVASION:
Present.
.
10. RIGHT SUBMANDIBULAR GLAND (EXCISION): BENIGN SALIVARY GLAND.
NEGATIVE FOR TUMOR.
.
***** End of Diagnosis *****

[page 2 of 2]
Clinical History:
FLOOR OF MOUTH ALVEOLI TUMOR

Source: NCI Genomic Data Commons file eb2e2ab3-2e4e-4937-a9e7-cff954cadf74 (TCGA-BB-8601.8D54D670-025A-4306-8952-97A54EBF9506.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).